Gene-level copy-number profile of tumor specimen TCGA-AC-A6IV-01A from TCGA case TCGA-AC-A6IV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 48.0 years (17,521 days).
Specimen TCGA-AC-A6IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.52fad299-e76e-48e7-a770-c7737f5cd89c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A6IV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecd97e3a-9a4e-4028-bb43-555dcaef48f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,315; copy number 2: 47,592; copy number 3: 5,340; copy number 4: 855; copy number 5: 718.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A6IV-01A-12D-A33D-01): tumor purity 0.3, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 718 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:23,753,689–30,822,110, 277 genes, copy number 5 (broad region; genes not listed).
- chr17:49,085,511–53,106,358, 118 genes, copy number 5 (broad region; genes not listed).
- chr17:53,353,427–53,682,111, 4 genes, copy number 5: AC005341.1, AC090079.1, AC090079.2, AC034268.1.
- chr17:56,791,913–66,278,664, 319 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
